Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4823, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4823-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT, HAND-ASSISTED LAPAROSCOPIC RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CLEAR CELL (CONVENTIONAL) TYPE, MODERATELY DIFFERENTIATED, FUHRMAN GRADE 2/4 (3.5 CM.).
- B. THE TUMOR DOES NOT INVADE THE RENAL CAPSULE NOR THE RENAL VEIN.
- C. ALL SURGICAL RESECTION MARGINS ARE NEGATIVE FOR MALIGNANCY.
- D. FOCAL CHRONIC TUBULAR INTERSTITIAL DISEASE IN THE RENAL PARENCHYMA.
- E. RIGHT ADRENAL GLAND WITH NODULAR HYPERPLASIA, WITH NO EVIDENCE OF MALIGNANCY.
- F. TNM STAGE: pT1A, NX, MX.

Final Diagnosis

RECEIVED 17 SLIDES [REDACTED] LABELED "RIGHT KIDNEY MASS, FINE NEEDLE ASPIRATION":

- A. EXTREMELY SCANT SPECIMEN INSUFFICIENT FOR DEFINITIVE DIAGNOSIS. (see comment)
- B. RARE ATYPICAL CLEAR CELLS NOTED. (see comment)
- C. Rare glomeruli and tubular cells noted.

Comment:

Twelve smears, 3 Thinprep slides, and 2 cell block slides were reviewed.

The aspirate is very scant and predominantly consists of blood.

One (slide 1C2) of the cell block slides show rare atypical clear cells with some scattered hemosiderin pigment. However, the paucity of the atypical cells precludes a definitive diagnosis. Rare glomeruli and benign tubular cells are also identified.

Repeat sampling is recommended for a definitive diagnosis.

Source: NCI Genomic Data Commons file 749d084c-3b28-41d1-ac76-9151ab0b3445 (TCGA-B0-4823.690F1249-5E3C-4C07-951E-7168DC0DA62A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).